Somatic mutation profile of tumor specimen 0DX2D0 from CCDI case PBCPHI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.8 years (2,110 days).
Specimen 0DX2D0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dcd06b99-1e11-4754-baa4-2770ff14407b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DX2CD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/267357eb-784d-48f7-b05c-aa620ce4c896

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 4, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANK2 | c.470G>A p.S157N | Missense Mutation (SNP) | VAF 30/894 reads (3%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV52174241; called by muse, mutect2
- DIAPH1 | c.3394G>A p.E1132K | Missense Mutation (SNP) | VAF 42/904 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53890561; called by muse, mutect2
- STAT5B | c.1246T>C p.F416L | Missense Mutation (SNP) | VAF 17/478 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.299); catalogued as COSV53186227; called by muse, mutect2
- POLN | c.815A>C p.E272A | Missense Mutation (SNP) | VAF 32/536 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2
- HLA-DQA1 | c.483C>A p.T161= | Silent (SNP) | VAF 157/227 reads (69%) | called by muse, mutect2, varscan2
- KEL | c.180T>C p.C60= | Silent (SNP) | VAF 205/501 reads (41%) | catalogued as rs765242978; called by muse, mutect2, varscan2
- NYNRIN | c.3684G>A p.V1228= | Silent (SNP) | VAF 14/329 reads (4%) | called by muse, mutect2
